Gene-level copy-number profile of tumor specimen TCGA-77-8128-01A from TCGA case TCGA-77-8128, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.2 years (21,986 days).
Specimen TCGA-77-8128-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.690d4585-8062-4a22-96b5-bda97ef9843b.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,490 have no estimate.
https://portal.gdc.cancer.gov/files/9aa566ee-1eef-4f8e-82ae-c0426fcbdc38

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 862; copy number 2: 14,680; copy number 3: 23,244; copy number 4: 12,332; copy number 5: 1,839; copy number 6: 430; copy number 7: 1,656.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8128-01A-11D-2243-01): tumor purity 0.64, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,789,179–25,089,151, 90 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,656 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:165,772,904–188,890,671, 395 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:54,933,699–55,255,635, 5 genes, copy number 7 (within-gene range 4–7): AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.
- chr8:37,559,992–43,085,788, 139 genes, copy number 7 (broad region; genes not listed).
- chr8:127,072,694–127,227,541, 1 gene, copy number 7 (within-gene range 4–7): CASC19.
- chr8:127,253,213–127,482,139, 5 genes, copy number 7 (within-gene range 4–7): AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2.
- chr9:26,903,372–36,677,683, 239 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr17:76,081,016–76,470,117, 18 genes, copy number 7: EXOC7, AC018665.1, MIR6868, FOXJ1, RNF157-AS1, RNF157, ATP5MGP6, ATF4P3, UBALD2, QRICH2, PRPSAP1, Y_RNA, RNU6-24P, AC090699.1, SPHK1, UBE2O, RPL7P49, AANAT.
- chr19:39,553,034–40,576,464, 54 genes, copy number 7 (within-gene range 2–7): AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4.
- chr22:16,953,895–35,503,586, 800 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 862. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
